Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5006, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5006-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 5006

Clinical Diagnosis & History:

Left renal mass, left partial nephrectomy.

Specimens Submitted:

- 1: SP: Kidney, left upper pole, partial nephrectomy
- 2: SP: Kidney, left lower pole hilum, partial nephrectomy
- 3: SP: Lymph nodes, para-aortic, excision
- 4: SP: Perinephric fat, left upper pole, excision

DIAGNOSIS:

1. SP: Kidney, left upper pole, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 3.0 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild patchy interstitial chronic inflammation

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. SP: Kidney, left lower pole hilum, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Papillary type

[page 2 of 4]
[REDACTED]

partially cystic, with low nuclear grade (see comment)

Tumor Size:

Greatest diameter is 3.0 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild patchy interstitial chronic inflammation

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

Comment: The tumor cells are positive for CK7 and racemase. CA-9 stains tumor cells around areas of necrosis and hemorrhage. This immunoprofile supports the diagnosis.

3. SP: Lymph nodes, para-aortic, excision:

Lymph Nodes:

Not involved

Number of nodes examined:2

4. Perinephric fat, left upper pole, excision:

Benign fibroadipose tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Special Studies:

Result

Special Stain
RACEMASE
CK7
CA-1X.
NEG CONT
IMM RECUT

Comment

Gross Description:

[REDACTED]

[page 3 of 4]
1). The specimen is received fresh for frozen section consultation and is labeled "left upper pole kidney tumor, stitch marks deepest surgical margin". It consists of a 4.5 x 3.0 x 2.0 cm wedge shaped portion of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a bright yellow well circumscribed tumor with focal hemorrhage measuring 3.0 x 2.0 x 2.0 cm. The clearance from the resection margin is 0.1 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for [REDACTED]

Summary of sections:

FSC - frozen section control
TC - tumor with renal capsule
TM - tumor to margin
TK - tumor with normal kidney
RS - representative section

[REDACTED]

2). The specimen is received fresh for frozen section consultation labeled "left lower pole hilar tumor (kidney) stitch marks deep margin". It consists of a 4.8 x 3.7 x 2.3 cm piece of renal parenchyma. The resected margin is inked black. Cut section of the specimen reveals a 3.0 x 3.0 x 3.0 cm friable bloody cystic tumor which is located 0.1 cm from the closest deep margin. A representative section is submitted for frozen section consultation. A sample is given to [REDACTED] Representative sections are submitted.

Summary of sections:

FSC - frozen section control
T-tumor with margin
TC-tumor with capsule

[REDACTED]

3). The specimen is received in formalin labeled "para-aortic lymph nodes". It consists of multiple lymph nodes measuring up to 5.5 x 2.5 cm in greatest dimensions. The lymph nodes are serially sectioned at 3 mm intervals and submitted.

Summary of sections:

LN1-lymph node number one
LN2-lymph node number two
LN-lymph nodes
BLN-bisected lymph node

[REDACTED]

4). The specimen is received in formalin labeled "upper pole peritumoral fat (kidney left)". It consists of two pieces of yellow-tan fatty tissue measuring 6.5 x 6.0 x 1.8 cm in aggregate. On sectioning the tissue there is no discrete tumor nodule identified. Representative sections are submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Kidney, left upper pole, partial nephrectomy

Block	Sect. Site	PCs
1	FSC	1
1	RS	1
1	TC	1
1	TK	1
1	TM	1

Part 2: SP: Kidney, left lower pole hilum, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
2	t	2
1	tc	1

[page 4 of 4]
Part 3: SP: Lymph nodes, para-aortic, excision

Block	Sect. Site	PCs
4	bln	4
1	ln	1
5	ln1	5
3	ln2	3

Part 4: SP: Perinephric fat, left upper pole, excision

Block	Sect. Site	PCs
2	u	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA. MARGIN AT STITCH FREE OF TUMOR. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA. MARGIN AT STITCH FREE OF TUMOR
(TUMOR 0.5 MM AWAY FROM CLOSEST MARGIN). [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file 704c7cc7-c259-4d32-9d8e-dd8128ac9a71 (TCGA-BP-5006.CD7DE55A-5445-4C0A-96F5-3CBC9486ADC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).